Somatic mutation profile of tumor specimen MMRF_2368_1_BM_CD138pos (aliquot MMRF_2368_1_BM_CD138pos_T1_KHS5U_L11030) from MMRF case MMRF_2368, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.0 years (30,330 days).
Specimen MMRF_2368_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e15ab57-c877-44eb-873b-7bb6b8f71956.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2368_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2368_1_PB_WBC_C2_KHS5U_L11029; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c4e6fe8-9e91-49cb-aadb-0f5cc0184e58

The open-access MAF lists 65 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 19, Missense Mutation 19, Intron 15, Silent 7, 5'Flank 2, 5'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 42/143 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 43/95 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARVCF | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs775595848; called by muse, mutect2, varscan2
- BMX | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV59591750; called by muse, mutect2, varscan2
- GPC6 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1391009706, COSV104425017; called by muse, varscan2
- PDZD2 | c.2287G>A p.G763R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226136; called by muse, mutect2, varscan2
- PRPF18 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1022619668; called by muse, mutect2, varscan2
- RUFY4 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1239629418, COSV60246124; called by muse, mutect2, varscan2
- CCN3 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF2 | c.1994T>A p.I665N | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HMX1 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- METTL15 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- NPAS3 | c.391G>T p.G131C (on ENST00000356141 / NM_001164749.2; = p.X99_splice on NM_022123.3) | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- OSBPL7 | c.388T>G p.F130V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- PGM2 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POU3F2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PTPRO | c.2141_2151delinsAG p.S714_R717delins* | Nonsense Mutation (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2*
- SCAF4 | c.2848C>A p.Q950K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, varscan2
- TRIM24 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BAZ2A | c.369C>G p.L123= | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- CCDC62 | c.1404G>A p.L468= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- FMNL1 | c.825G>T p.L275= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, varscan2
- IGHA2 | c.189G>A p.L63= | Silent (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.162C>T p.Y54= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs372746871; called by muse, mutect2, varscan2
- LIPC | c.969G>A p.T323= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs539127704; called by muse, mutect2, varscan2
- U2AF2 | c.1077A>G p.Q359= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV58276104; called by muse, mutect2, varscan2
- AC073310.1 | n.729T>C | RNA (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- ACP6 | c.1143+36G>A | Intron (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+4790G>T | Intron (SNP) | VAF 77/246 reads (31%) | called by muse, mutect2, varscan2
- BMF | c.*979C>T | 3'UTR (SNP) | VAF 33/134 reads (25%) | called by muse, mutect2, varscan2
- CCDC102B | c.1053+47C>G | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2
- CCDC174 | c.820-33T>A | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- CCSER2 | c.*3773G>A | 3'UTR (SNP) | VAF 30/92 reads (33%) | catalogued as COSV99826694; called by muse, mutect2, varscan2
- CEP135 | c.699+796G>A | Intron (SNP) | VAF 23/114 reads (20%) | catalogued as rs926920548; called by muse, mutect2, varscan2
- CTSC | c.*271A>G | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- FMNL1 | c.2449-17C>A | Intron (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- FMNL1 | c.3091-55C>T | Intron (SNP) | VAF 18/96 reads (19%) | called by muse, varscan2
- GABRB3 | c.*2715G>A | 3'UTR (SNP) | VAF 14/76 reads (18%) | catalogued as COSV54671017; called by muse, mutect2
- GLB1 | c.1069-67T>A | Intron (SNP) | VAF 4/9 reads (44%) | called by muse, varscan2
- GLP2R | c.*155_*160dup | 3'UTR (INS) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- GSK3B | c.-407T>A | 5'UTR (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- GTF2A2 | c.72+165G>A | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- IGLC2 | c.*116A>G | 3'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as rs1221002542; called by muse, mutect2
- IGLC2 | c.*118A>G | 3'UTR (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2
- KCND2 | c.*1001_*1006del | 3'UTR (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- LRATD1 | c.*4968C>A | 3'UTR (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- LRPAP1 | c.350-24A>G | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- LTB | c.162+188C>T | Intron (SNP) | VAF 38/93 reads (41%) | catalogued as rs1489894238; called by muse, mutect2, varscan2
- MDGA2 | c.*1199T>A | 3'UTR (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- MRPL50 | c.*2106A>G | 3'UTR (SNP) | VAF 44/154 reads (29%) | called by muse, mutect2, varscan2
- PARP1 | c.286+371T>C | Intron (SNP) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- PIEZO2 | chr18:11148652 G>A | 5'Flank (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PIGX | c.*335A>T | 3'UTR (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- RBM4B | c.*10-1163_*10-1162del | Intron (DEL) | VAF 6/41 reads (15%) | called by pindel, varscan2
- RGL1 | c.*1368G>T | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- SLC9A6 | c.*2495G>A | 3'UTR (SNP) | VAF 6/65 reads (9%) | catalogued as rs1027921341; called by muse, mutect2
- TJP1 | c.1010+2121C>T | Intron (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- TLL1 | c.*1816A>C | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- TLR4 | c.*1784del | 3'UTR (DEL) | VAF 18/80 reads (23%) | called by mutect2, varscan2
- TSC1 | c.*4366C>G | 3'UTR (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- WDR86 | chr7:151411764 C>T | 5'Flank (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- YIPF6 | c.*1318A>G | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- YY2 | c.*394G>A | 3'UTR (SNP) | VAF 4/42 reads (10%) | catalogued as rs1484404104; called by muse, mutect2
- ZNF783 | c.803-2049A>T | Intron (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
